Somatic mutation profile of tumor specimen 1105232 (aliquot 7316UP-498-1105232) from CPTAC case C330255, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Occipital lobe; Tumor grade: G4.
Specimen 1105232: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dfc8ade-2e01-458d-b66a-9bedd788437a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105212 (Blood Derived Normal), aliquot 7316UP-361-1105212; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/102d1a84-5858-4b2f-9ef9-5461e01feaa2

The open-access MAF lists 67 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 11, Nonsense Mutation 4, Intron 4, 5'Flank 2, RNA 2, 5'UTR 1, Frame Shift Del 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3145G>A p.G1049S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs750641202, COSV58639892; called by muse, mutect2, varscan2
- AFF2 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99663577; called by muse, mutect2, varscan2
- AK7 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs767780619, COSV50871179; called by muse, mutect2, varscan2
- BECN1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV64120591; called by muse, mutect2, varscan2
- CDH23 | c.3802G>A p.V1268M | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as rs201884261, COSV56495432; ClinVar: uncertain significance; called by muse, mutect2
- DDX3X | c.982G>A p.D328N (on ENST00000399959; = p.D329N on NM_001356.5) | Missense Mutation (SNP) | VAF 124/378 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101302320, COSV101302559; called by muse, mutect2, varscan2
- EMILIN3 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 92/428 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs751404791, COSV60035122; called by muse, mutect2, varscan2
- GAD2 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757006706; called by muse, mutect2, varscan2
- GATA6 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 127/401 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1372369528, COSV52528013; called by muse, mutect2, varscan2
- GRIN2B | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 142/470 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1428234478, COSV74204916; called by muse, mutect2, varscan2
- H2BC1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as rs776852235; called by muse, mutect2, varscan2
- KRT19 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs758074102, COSV99563255; called by muse, mutect2, varscan2
- MUC12 | c.13126A>G p.S4376G (on ENST00000379442; = p.S4233G on NM_001164462.1) | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (1); catalogued as rs200462783; called by muse, mutect2, varscan2
- MUC17 | c.9893C>T p.T3298M | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs763282881; called by muse, mutect2, varscan2
- MUC5B | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs373277856; called by muse, mutect2, varscan2
- NAA25 | c.665A>G p.E222G | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV55702864; called by muse, mutect2, varscan2
- NPC1 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 146/388 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs140786703; called by muse, mutect2, varscan2
- PCDH1 | c.2165C>G p.S722C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54615324; called by muse, mutect2, varscan2
- PCLO | c.9716G>A p.R3239H | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779385664, COSV61613933; called by muse, mutect2, varscan2
- PPP3CB | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV55019745; called by muse, mutect2, varscan2
- PROKR2 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs753089596, COSV54086246, COSV99450151; called by muse, mutect2, varscan2
- RBMXL3 | c.2816G>A p.R939Q | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs782526835; called by muse, mutect2, varscan2
- RGS3 | c.3504C>A p.F1168L (on ENST00000350696 / NM_001282923.2; = p.F887L on NM_130795.4) | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV100637009; called by muse, mutect2, varscan2
- RPH3A | c.805C>T p.R269W (on ENST00000389385 / NM_001143854.2; = p.R265W on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); catalogued as rs760123095, COSV101231776; called by muse, mutect2, varscan2
- SDC4 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201484099; called by muse, mutect2, varscan2
- SRPX | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs750284952, COSV100656054; called by muse, mutect2, varscan2
- STPG3 | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 121/358 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs1390662039; called by muse, mutect2, varscan2
- CUBN | c.4133del p.R1378Lfs*85 | Frame Shift Del (DEL) | VAF 138/342 reads (40%) | called by mutect2, pindel, varscan2
- EGFL6 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GSTA3 | c.495C>A p.Y165* | Nonsense Mutation (SNP) | VAF 81/222 reads (36%) | called by muse, mutect2, varscan2
- MYO10 | c.4253G>A p.W1418* | Nonsense Mutation (SNP) | VAF 52/163 reads (32%) | called by muse, mutect2, varscan2
- NFATC1 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRK | c.4724A>T p.E1575V | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- OR4S2 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- OXGR1 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PKP2 | c.1510+1G>A p.X504_splice | Splice Site (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- PRSS16 | c.791C>A p.A264E | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SMOX | c.1019A>T p.Q340L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TBC1D8B | c.2941A>T p.I981F | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.603); called by muse, varscan2
- TDRD7 | c.2699A>T p.E900V | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TMTC1 | c.2620C>T p.Q874* (on ENST00000539277 / NM_001193451.2; = p.Q766* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 56/177 reads (32%) | called by muse, mutect2, varscan2
- WDFY3 | c.5533G>A p.G1845R | Missense Mutation (SNP) | VAF 88/284 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZC2HC1C | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.238); called by muse, varscan2
- ZCCHC8 | c.1077C>G p.Y359* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | called by muse, mutect2, varscan2
- ZNF416 | c.906G>T p.Q302H | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BRINP3 | c.912T>C p.L304= | Silent (SNP) | VAF 58/143 reads (41%) | called by muse, mutect2, varscan2
- CEP350 | c.2943A>G p.S981= | Silent (SNP) | VAF 65/212 reads (31%) | called by muse, mutect2, varscan2
- CFAP20DC | c.1767A>G p.Q589= | Silent (SNP) | VAF 110/264 reads (42%) | called by muse, mutect2, varscan2
- GAS2 | c.738A>G p.K246= | Silent (SNP) | VAF 72/198 reads (36%) | catalogued as rs529708585; called by muse, mutect2
- IBSP | c.351C>T p.D117= | Silent (SNP) | VAF 53/190 reads (28%) | catalogued as rs779776336, COSV56896798; called by muse, mutect2, varscan2
- LRRC3B | c.570C>T p.N190= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as rs375239096; called by muse, mutect2, varscan2
- MTUS2 | c.147C>T p.D49= | Silent (SNP) | VAF 60/151 reads (40%) | catalogued as rs183635259, COSV70917993; called by muse, mutect2, varscan2
- RAB35 | c.297C>G p.V99= | Silent (SNP) | VAF 54/210 reads (26%) | called by muse, mutect2, varscan2
- TRRAP | c.8565C>T p.C2855= (on ENST00000359863 / NM_001244580.1; = p.C2837= on NM_003496.3) | Silent (SNP) | VAF 100/485 reads (21%) | catalogued as rs777625422, COSV62840828; called by muse, mutect2, varscan2
- VPS25 | c.348C>T p.S116= | Silent (SNP) | VAF 63/223 reads (28%) | catalogued as rs1051997463, COSV53822367; called by muse, mutect2, varscan2
- ZCCHC14 | c.1893C>T p.H631= (on ENST00000268616; = p.H768= on NM_015144.3) | Silent (SNP) | VAF 70/184 reads (38%) | catalogued as rs1343391889; called by muse, mutect2, varscan2
- AGPAT2 | c.-21C>T | 5'UTR (SNP) | VAF 78/192 reads (41%) | catalogued as rs1340169329; called by muse, mutect2, varscan2
- ATP5F1B | c.310+100del | Intron (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- DEUP1 | c.1638+77C>T | Intron (SNP) | VAF 14/49 reads (29%) | catalogued as rs186846330; called by muse, mutect2, varscan2
- FAM13B | chr5:138036651 del TAAC | 5'Flank (DEL) | VAF 20/65 reads (31%) | called by mutect2, pindel, varscan2
- FKBP6 | c.57+45C>T | Intron (SNP) | VAF 72/377 reads (19%) | catalogued as rs781951342; called by muse, mutect2, varscan2
- MIR758 | n.51G>A | RNA (SNP) | VAF 13/80 reads (16%) | catalogued as rs757142896; called by muse, mutect2, varscan2
- MMAB | c.*3065G>A | 3'UTR (SNP) | VAF 153/536 reads (29%) | catalogued as rs981927317; called by muse, mutect2, varscan2
- OR5P1P | n.733G>A | RNA (SNP) | VAF 35/97 reads (36%) | catalogued as rs1182308743; called by muse, mutect2, varscan2
- STAU1 | c.206-4874A>G | Intron (SNP) | VAF 52/240 reads (22%) | called by muse, mutect2, varscan2
- TRHDE | chr12:72271904 C>G | 5'Flank (SNP) | VAF 57/165 reads (35%) | catalogued as rs1194899367; called by muse, mutect2, varscan2
